FM case AD14690 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/76403995-3769-4670-beb9-581d19e9cda5

Male, 70.3 years: Carcinoma, NOS (ICD-O-3 8010/3); specimen biopsied or resected from the head, face or neck. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
